Somatic mutation profile of tumor specimen TCGA-KO-8410-01A (aliquot TCGA-KO-8410-01A-11D-2310-10) from TCGA case TCGA-KO-8410, project TCGA-KICH (Kidney Chromophobe). Sex at birth: female; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, chromophobe type; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 74.2 years (27,084 days).
Specimen TCGA-KO-8410-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f34b60c4-4d26-4114-a281-da61f57469c4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-KO-8410-11A (Solid Tissue Normal), aliquot TCGA-KO-8410-11A-01D-2311-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/14a89838-b447-4e34-a456-95e6c1888b18

The open-access MAF lists 18 somatic variants for this specimen: 13 protein-altering or splice-affecting, 1 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, 3'UTR 2, Nonsense Mutation 1, Silent 1, Frame Shift Del 1, 5'Flank 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADD2 | c.1057G>T p.G353W | Missense Mutation (SNP) | VAF 12/162 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as COSV100035181; called by muse, mutect2
- ADGRL3 | c.655T>C p.S219P (on ENST00000506720 / NM_001322402.2; = p.S151P on NM_015236.6) | Missense Mutation (SNP) | VAF 5/84 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as COSV101546958; called by muse, mutect2
- ADHFE1 | c.355T>G p.F119V | Missense Mutation (SNP) | VAF 35/84 reads (42%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.909); catalogued as COSV99397678; called by muse, mutect2, varscan2
- AMPD1 | c.1356C>G p.Y452* | Nonsense Mutation (SNP) | VAF 8/75 reads (11%) | catalogued as COSV100814815, COSV100814969; called by muse, mutect2, varscan2
- CCDC191 | c.25T>G p.S9A | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT tolerated (0.4); PolyPhen benign (0.006); catalogued as COSV99846851; called by muse, mutect2, varscan2
- CNBD2 | c.1345T>A p.L449M (on ENST00000373973 / NM_001365709.1; = p.L445M on NM_080834.4) | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.006); catalogued as COSV100839066; called by muse, mutect2
- LMBRD2 | c.608G>A p.G203E | Missense Mutation (SNP) | VAF 65/107 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99682723; called by muse, mutect2, varscan2
- LZTS2 | c.302C>T p.P101L | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as rs753214488, COSV100932126; called by muse, mutect2, varscan2
- OR13C2 | c.47G>A p.G16E | Missense Mutation (SNP) | VAF 28/308 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV101604863; called by muse, mutect2
- PASK | c.920C>T p.T307I | Missense Mutation (SNP) | VAF 30/109 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.708); catalogued as COSV99299023; called by muse, mutect2, varscan2
- SLC4A10 | c.1405G>A p.G469R (on ENST00000446997 / NM_001354461.2; = p.G439R on NM_022058.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 30/184 reads (16%) | SIFT tolerated (0.48); PolyPhen benign (0.14); catalogued as rs755119585, COSV99763186; called by muse, mutect2, varscan2
- SLCO1B3-SLCO1B7 | c.2062G>A p.G688S (on ENST00000540229 / NM_001371097.1; = p.G627S on NM_001009562.4) | Missense Mutation (SNP) | VAF 21/201 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.149); catalogued as rs112108376; called by muse, mutect2, varscan2
- ITGA2 | c.2980_2983del p.P994Sfs*9 | Frame Shift Del (DEL) | VAF 23/52 reads (44%) | called by mutect2, pindel, varscan2
- FRAS1 | c.8697C>T p.A2899= | Silent (SNP) | VAF 69/193 reads (36%) | catalogued as rs536123620, COSV53616575; called by muse, mutect2, varscan2
- PABPC3 | c.*222del | 3'UTR (DEL) | VAF 6/38 reads (16%) | catalogued as rs546832719; called by mutect2, varscan2
- PRND | c.*3172C>T | 3'UTR (SNP) | VAF 14/112 reads (13%) | catalogued as COSV99999453; called by muse, mutect2, varscan2
- TMEM30B | chr14:61281634 T>G | 5'Flank (SNP) | VAF 24/81 reads (30%) | catalogued as COSV100855708; called by muse, mutect2, varscan2
- ZNF840P | n.35T>A | RNA (SNP) | VAF 74/226 reads (33%) | called by muse, mutect2, varscan2
